Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4993, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4993-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA-BP-4993

Clinical Diagnosis & History:

with incidental bilateral renal masses, now left nephrectomy.

Specimens Submitted:

1: Kidney, left, upper pole kidney mass, partial nephrectomy

DIAGNOSIS:

1. Kidney, left, upper pole kidney mass, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 2.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not Identified

Surgical Margins:

Free of tumor
see comment

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not Identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

Comment: Tumor is identified very close, less than 0.2 mm from the inked margin

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1.) The specimen is received fresh, labeled "left upper pole kidney mass". It consists of a 5.5 x 3.8 x 3.0 cm wedge shaped portion of kidney, with attached perirenal fat. The margin is inked black and the specimen is serially sectioned to reveal an ovoid, golden yellow, partly hemorrhagic, encapsulated mass measuring 2.5 x 2.3 x 2.1 cm. The tumor bulges towards the resection margin. The clearance from the resection margin in this area is less than 0.1 cm. The surrounding kidney parenchyma is unremarkable. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

T - tumor

TM - tumor in relation to margin

UK- uninvolved kidney

Summary of Sections:

Part 1: Kidney, left, upper pole kidney mass, partial nephrectomy

Block	Sect. Site	PCs
2	T	2
3	TM	3
1	UK	1

Source: NCI Genomic Data Commons file 2ad264be-86f8-430f-9f0b-acea5952414c (TCGA-BP-4993.85BFA05C-EFEF-45C6-951B-37B4E9675138.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).